Somatic mutation profile of tumor specimen 0DAU02 from CCDI case PBBKDD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.6 years (6,069 days).
Specimen 0DAU02: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5e25a02-25d3-4244-9271-cf04b380b7ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DATZY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0355b02a-e9a3-495f-a3ec-c7a8882e06f6

The open-access MAF lists 22 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, 3'UTR 1, Intron 1, Nonstop Mutation 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 107/472 reads (23%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 72/1026 reads (7%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- BCORL1 | c.3793C>T p.R1265C | Missense Mutation (SNP) | VAF 58/372 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.346); catalogued as rs1464137864, COSV54393793; called by muse, mutect2, varscan2
- INF2 | c.733C>G p.L245V | Missense Mutation (SNP) | VAF 52/413 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.906); catalogued as rs765986755; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MSMO1 | c.790A>G p.T264A | Missense Mutation (SNP) | VAF 177/1200 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.705); catalogued as rs1233010356; called by muse, mutect2, varscan2
- OR2T8 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 24/882 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.103); catalogued as rs758294510, COSV100177951, COSV100178597; called by muse, mutect2
- SPAST | c.164A>G p.Y55C | Missense Mutation (SNP) | VAF 50/420 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV59517733; called by muse, mutect2, varscan2
- TMTC2 | c.1169C>T p.T390M | Missense Mutation (SNP) | VAF 127/786 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs147409383; called by muse, mutect2, varscan2
- TTN | c.86477G>A p.R28826H (on ENST00000591111; = p.R21402H on NM_003319.4) | Missense Mutation (SNP) | VAF 165/509 reads (32%) | PolyPhen benign (0.034); catalogued as rs572793448; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACSL4 | c.529+1G>A p.X177_splice (on ENST00000340800 / NM_022977.2; = p.X136_splice on NM_004458.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 150/880 reads (17%) | called by muse, mutect2, varscan2
- CC2D1A | c.2341G>A p.G781R | Missense Mutation (SNP) | VAF 20/734 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GIMAP4 | c.990A>C p.*330Yext*2 | Nonstop Mutation (SNP) | VAF 52/404 reads (13%) | called by muse, mutect2, varscan2
- SIK3 | c.3472A>G p.T1158A (on ENST00000445177 / NM_001366686.2; = p.T1116A on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); called by muse, mutect2
- TRIP4 | c.688C>T p.L230F | Missense Mutation (SNP) | VAF 180/690 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- WASHC2A | c.255C>A p.D85E | Missense Mutation (SNP) | VAF 155/1056 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- KLHL34 | c.1401G>A p.A467= | Silent (SNP) | VAF 121/644 reads (19%) | called by muse, mutect2, varscan2
- MMP26 | c.138G>A p.S46= | Silent (SNP) | VAF 159/674 reads (24%) | catalogued as rs755146432, COSV56173276; called by muse, mutect2, varscan2
- PCCB | c.1425G>A p.G475= | Silent (SNP) | VAF 52/1146 reads (5%) | called by muse, mutect2
- SIPA1L1 | c.4344T>C p.L1448= | Silent (SNP) | VAF 80/782 reads (10%) | called by muse, mutect2, varscan2
- EYS | c.862+16G>T | Intron (SNP) | VAF 141/546 reads (26%) | called by muse, mutect2, varscan2
- PPP1R1A | chr12:54575945 T>C | 3'Flank (SNP) | VAF 28/333 reads (8%) | called by muse, mutect2
- RGSL1 | c.*66T>G | 3'UTR (SNP) | VAF 67/834 reads (8%) | called by muse, mutect2
